CPTAC case C224967 — Complex Epithelial Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Complex Epithelial Neoplasms. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/d4668df1-2055-4641-9fee-16d16edd7451

Demographics
Sex at birth: male; Age at index: 57 years; Vital status: Dead; Days to death: 726 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenosquamous carcinoma: ICD-O-3 morphology code: 8560/3; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 726 days (2.0 years); Progression or recurrence: yes; Days to recurrence: 326 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 35; Cigarettes per day: 20; Alcohol history: Yes.

Biospecimens (7 samples)
- Samples 1104786, 1104807, 1105199, 1105249, SM-JU33C, SM-JU33O (6 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample 1105291: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
